Gene-level copy-number profile of tumor specimen TCGA-VD-AA8N-01A from TCGA case TCGA-VD-AA8N, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 86.2 years (31,475 days).
Specimen TCGA-VD-AA8N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.55a3a570-add9-4ab4-8f3a-55f1d584e51c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-AA8N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-AA8N-01A|TCGA-VD-AA8N-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d91eaa7-77da-4265-a49a-b9070177e572

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,309; copy number 2: 48,972; copy number 3: 175; copy number 4: 1,292; copy number 5: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-AA8N-01A-11D-A39V-01): tumor purity 0.82, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:55,102,028–55,542,054, 1 gene, copy number 5 (within-gene range 3–5): XKR4.
- chr8:55,449,509–55,826,445, 5 genes, copy number 5: SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1.
- chr8:56,957,931–61,501,645, 61 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,888. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
